Somatic mutation profile of tumor specimen 0DKFA1 from CCDI case PBBXYP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.7 years (6,114 days).
Specimen 0DKFA1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fee956da-fa3c-4857-b23e-8542f7396968.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKF9N (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17a388fa-dcb3-43f7-8d11-03a7036997ba

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, RNA 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 283/493 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- COL4A5 | c.2522T>C p.I841T | Missense Mutation (SNP) | VAF 99/251 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CREBBP | c.5125_5134del p.E1709Tfs*32 | Frame Shift Del (DEL) | VAF 92/342 reads (27%) | called by mutect2, varscan2
- DPP9 | c.1729C>G p.L577V (on ENST00000598800; = p.L606V on NM_139159.5) | Missense Mutation (SNP) | VAF 223/654 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- KRTAP10-6 | c.592T>A p.S198T | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- TCF4 | c.742A>G p.I248V | Missense Mutation (SNP) | VAF 226/777 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CSF2RB | c.1725C>T p.A575= | Silent (SNP) | VAF 19/262 reads (7%) | catalogued as rs978813056, COSV53261029; called by muse, mutect2
- LRRC61 | c.681G>A p.L227= | Silent (SNP) | VAF 80/382 reads (21%) | called by muse, mutect2, varscan2
- MYO18B | c.2397G>A p.A799= | Silent (SNP) | VAF 246/715 reads (34%) | catalogued as rs766198504, COSV59131997; called by muse, mutect2
- AC007568.1 | n.430T>G | RNA (SNP) | VAF 75/277 reads (27%) | called by muse, mutect2, varscan2
- EIF4A3 | c.728+84T>C | Intron (SNP) | VAF 14/174 reads (8%) | catalogued as rs1432665924; called by muse, mutect2
